TCGA case TCGA-28-2506 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Cedars Sinai. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ec1791b3-0192-45da-89c1-f942a6736704

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 63 years; Vital status: Alive.

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 63.8 years (23,292 days); Year of diagnosis: 2009; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 27 days; Days to treatment end: 69 days; Treatment dose: 6,000 cGy; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 27 days; Days to treatment end: 72 days; Prescribed dose: 100; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Antineoplastic Vaccine; Treatment intent type: Adjuvant; Days to treatment start: 107 days; Days to treatment end: 135 days; Prescribed dose: 1.1; Prescribed dose units: mL.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Afatinib Dimaleate; Initial disease status: Progressive Disease; Days to treatment start: 177 days; Treatment outcome: Treatment Ongoing; Prescribed dose: 40; Prescribed dose units: mg; Route of administration: Oral.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 64.0 years (23,376 days); Days to diagnosis: 84 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 153 days.
   Recorded as not given: Pharmaceutical Therapy, NOS; Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS; Radiation Therapy, NOS, for progressive disease.

Follow-up (4 entries)
- Day 84 (post initial treatment): Progression or recurrence: Yes; Days to progression: 84 days.
- Days to follow up: 205 days; Disease response: With Tumor.
- Karnofsky performance status: 80; Timepoint: Post Adjuvant Therapy.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Timepoint: Post Initial Treatment.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-28-2506-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.2; Intermediate dimension: 0.5; Shortest dimension: 0.5.
  Slide TCGA-28-2506-01A-02-BS2: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-28-2506-01A-01-BS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-28-2506-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Performance status timing: Post-Adjuvant Therapy.
- Drug treatment 1: Pharmaceutical therapy drug name: Tumor Vaccine.
- Drug treatment 1, Route of administrations: Route of administration: Other (specify below).
- Drug treatment 2: Pharmaceutical therapy drug name: Temodar.
- Drug treatment 2, Route of administrations: Route of administration: PO.
- Drug treatment 3: Pharmaceutical therapy drug name: BIBW 2992.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 205 days; disease-specific survival: no event (censored), 205 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 84 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-28-2506-01A-02D-0784-01): tumor purity 0.51, ploidy 3.37, whole-genome doublings 1.
